Somatic mutation profile of tumor specimen ALCH-B2SM-TTP1-A (aliquot ALCH-B2SM-TTP1-A-2-0-D-A78Q-36) from ALCHEMIST case ALCH-B2SM, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 68.0 years (24,842 days).
Specimen ALCH-B2SM-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7a1516a7-f1b8-42cb-ae94-5c7123ae4723.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2SM-NB1-A (Blood Derived Normal), aliquot ALCH-B2SM-NB1-A-1-0-D-A78Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ba2a3a08-10f3-4387-ba34-ae058f64e4fe

The open-access MAF lists 331 somatic variants for this specimen: 216 protein-altering or splice-affecting, 71 silent, 44 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 184, Silent 71, Intron 21, Nonsense Mutation 14, 5'UTR 9, RNA 8, Splice Site 7, Frame Shift Del 6, 3'UTR 4, Frame Shift Ins 3, Splice Region 2, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.733G>T p.G245C | Missense Mutation (SNP) | VAF 82/150 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- WDR62 | c.1312C>T p.R438C | Missense Mutation (SNP) | VAF 39/418 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587784542; ClinVar: likely pathogenic; called by muse, mutect2
- ABCC9 | c.2338A>G p.R780G | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99686354; called by muse, varscan2
- ACTL6B | c.271G>C p.E91Q | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as COSV50514457, COSV50514641; called by muse, mutect2, varscan2
- AGTR1 | c.310G>T p.A104S | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV62557242; called by muse, varscan2
- ARG1 | c.936C>A p.H312Q | Missense Mutation (SNP) | VAF 74/87 reads (85%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as rs776119677; called by muse, mutect2, varscan2
- ARHGAP11A | c.983G>C p.R328P | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367930258; called by muse, mutect2, varscan2
- BRINP3 | c.1061G>C p.R354P | Missense Mutation (SNP) | VAF 51/178 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV66525489; called by muse, varscan2
- BTBD7 | c.1562G>T p.R521L | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs758664842; called by muse, mutect2, varscan2
- C8B | c.1334C>G p.T445R | Missense Mutation (SNP) | VAF 62/112 reads (55%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.502); catalogued as rs138837336; called by muse, mutect2, varscan2
- CALD1 | c.874C>T p.R292* | Nonsense Mutation (SNP) | VAF 70/167 reads (42%) | catalogued as rs142006920; called by muse, varscan2
- CCDC28A | c.494C>A p.S165Y | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.951); catalogued as COSV100236465, COSV100236563; called by muse, mutect2, varscan2
- CCDC73 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV58797270; called by muse, mutect2, varscan2
- CDK13 | c.3221C>G p.S1074* | Nonsense Mutation (SNP) | VAF 25/34 reads (74%) | catalogued as COSV51705517; called by muse, mutect2
- CHSY3 | c.1394A>T p.E465V | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.18); catalogued as COSV59276206; called by muse, mutect2, varscan2
- CLMN | c.885+1G>A p.X295_splice | Splice Site (SNP) | VAF 16/73 reads (22%) | catalogued as COSV54181974; called by muse, mutect2, varscan2
- CST4 | c.259G>A p.V87I | Missense Mutation (SNP) | VAF 122/369 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.087); catalogued as rs774067751, COSV99463147; called by muse, mutect2, varscan2
- CUL4B | c.550T>C p.S184P | Missense Mutation (SNP) | VAF 26/31 reads (84%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs748328122, COSV104414131; called by muse, mutect2, varscan2
- CYP4Z1 | c.1264C>G p.Q422E | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1404390352, COSV61964647; called by muse, mutect2, varscan2
- DDX3X | c.292C>T p.R98C (on ENST00000399959; = p.R99C on NM_001356.5) | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as rs1479548397, COSV67863277; called by muse, mutect2, varscan2
- DLGAP2 | c.2587C>A p.P863T | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as rs1229439807, COSV70098363; called by muse, mutect2, varscan2
- DNAH3 | c.9198C>G p.I3066M | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV54536401; called by muse, mutect2, varscan2
- DYNC1H1 | c.13509G>T p.E4503D | Missense Mutation (SNP) | VAF 96/258 reads (37%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as rs1304570979; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAM155A | c.853G>A p.V285M | Missense Mutation (SNP) | VAF 20/513 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.1); catalogued as COSV65572364; called by muse, mutect2
- FBXO5 | c.40C>T p.R14C | Missense Mutation (SNP) | VAF 83/108 reads (77%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.063); catalogued as rs914350637; called by muse, mutect2, varscan2
- FLT1 | c.2900C>G p.A967G | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.03); catalogued as rs371199947; called by muse, mutect2, varscan2
- FTO | c.1042G>T p.D348Y | Missense Mutation (SNP) | VAF 42/271 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as COSV67110777; called by muse, mutect2, varscan2
- GLCE | c.311A>G p.Y104C | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs757241878; called by muse, mutect2, varscan2
- HADHA | c.2281T>C p.F761L | Missense Mutation (SNP) | VAF 172/374 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1352427438; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HCN1 | c.1961C>A p.T654K | Missense Mutation (SNP) | VAF 757/1078 reads (70%) | SIFT tolerated (0.29); PolyPhen benign (0.04); catalogued as COSV57498316; called by muse, mutect2, varscan2
- HECTD4 | c.2852C>T p.A951V | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV61178398; called by muse, mutect2, varscan2
- IL17RA | c.1387dup p.A463Gfs*48 | Frame Shift Ins (INS) | VAF 36/82 reads (44%) | catalogued as rs755093612; called by mutect2, pindel, varscan2
- KLHL30 | c.631C>T p.R211W | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748756482; called by muse, mutect2, varscan2
- LATS1 | c.2008C>T p.R670W | Missense Mutation (SNP) | VAF 58/74 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1431439182, COSV53589766; called by muse, mutect2, varscan2
- MAB21L1 | c.334C>A p.L112I | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV59770193, COSV59788314; called by muse, mutect2, varscan2
- MARCHF1 | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs979367352, COSV56821714; called by muse, mutect2, varscan2
- MMRN1 | c.3479G>A p.G1160E | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53337418; called by muse, mutect2, varscan2
- MYO18A | c.5788G>T p.G1930W | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100572692; called by muse, mutect2, varscan2
- MYO18B | c.587C>G p.S196C | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.639); catalogued as rs1400466116; called by muse, varscan2
- MYOM1 | c.1951C>T p.R651W | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1042376495, COSV55293036; called by muse, mutect2, varscan2
- NLRP14 | c.2056G>A p.D686N | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as COSV55065458; called by muse, mutect2, varscan2
- NT5C1B | c.828C>A p.D276E (on ENST00000359846 / NM_001199086.2; = p.D216E on NM_033253.4) | Missense Mutation (SNP) | VAF 114/310 reads (37%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.003); catalogued as COSV58394213, COSV58394465; called by muse, varscan2
- NTRK2 | c.2069T>A p.V690E (on ENST00000323115 / NM_001369534.1; = p.V706E on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 81/142 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52879858; called by muse, mutect2, varscan2
- OR2A25 | c.123C>A p.N41K | Missense Mutation (SNP) | VAF 147/270 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68716840; called by muse, mutect2, varscan2
- OR2L3 | c.882G>T p.K294N | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV100742018; called by muse, mutect2
- OR2L3 | c.883G>T p.E295* | Nonsense Mutation (SNP) | VAF 16/48 reads (33%) | catalogued as rs1243984309; called by muse, mutect2
- OR2T6 | c.386C>A p.P129Q | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV63216791; called by muse, mutect2, varscan2
- OR4K5 | c.716C>G p.T239R | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60003373; called by muse, mutect2, varscan2
- OR5J2 | c.335G>T p.G112V | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.079); catalogued as rs758333440; called by muse, mutect2, varscan2
- OR5M1 | c.379T>C p.C127R | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV101591583; called by muse, mutect2, varscan2
- OTOG | c.5804T>A p.M1935K | Missense Mutation (SNP) | VAF 46/81 reads (57%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs61732913; called by muse, mutect2, varscan2
- P4HB | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 44/85 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs1362198352; called by muse, mutect2, varscan2
- PCDHB10 | c.1468C>A p.L490M | Missense Mutation (SNP) | VAF 85/163 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs782556940; called by muse, mutect2, varscan2
- PCNX1 | c.6496C>T p.Q2166* | Nonsense Mutation (SNP) | VAF 99/241 reads (41%) | catalogued as rs1345759249, COSV53089213; called by muse, mutect2, varscan2
- PDCL2 | c.51del p.F17Lfs*27 | Frame Shift Del (DEL) | VAF 22/73 reads (30%) | catalogued as COSV55260095; called by mutect2, pindel, varscan2
- PHIP | c.4802C>G p.S1601* | Nonsense Mutation (SNP) | VAF 23/78 reads (29%) | catalogued as rs1189684322; called by muse, mutect2, varscan2
- PKD1L3 | c.1942G>A p.A648T | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs756549601, COSV100626568; called by muse, varscan2
- PLB1 | c.406G>T p.D136Y | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.121); catalogued as COSV59830748; called by muse, mutect2, varscan2
- PLCXD3 | c.423C>G p.F141L | Missense Mutation (SNP) | VAF 15/286 reads (5%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV60606301; called by muse, mutect2
- PLEKHA6 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 60/235 reads (26%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.952); catalogued as rs769677464; called by muse, mutect2, varscan2
- PLXNA4 | c.4006C>T p.R1336W | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1009776638; called by muse, mutect2, varscan2
- PML | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 79/144 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.081); catalogued as rs772139210; called by muse, mutect2, varscan2
- POTEC | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.001); catalogued as rs764346159, COSV100743929, COSV62801882; called by muse, mutect2, varscan2
- PPM1A | c.985G>T p.D329Y | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100348770, COSV57785384; called by muse, mutect2, varscan2
- PPP1R3C | c.64G>T p.V22L | Missense Mutation (SNP) | VAF 92/186 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs754313291; called by muse, mutect2, varscan2
- PROS1 | c.1156-1G>T p.X386_splice | Splice Site (SNP) | VAF 6/32 reads (19%) | catalogued as CS163633, CS971882; called by muse, mutect2
- RBMS2 | c.556G>C p.E186Q | Missense Mutation (SNP) | VAF 46/142 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as COSV56262780, COSV56262937; called by muse, mutect2, varscan2
- SESTD1 | c.1465C>T p.R489* | Nonsense Mutation (SNP) | VAF 7/15 reads (47%) | catalogued as COSV58930399; called by muse, mutect2, varscan2
- SETDB1 | c.2977G>T p.G993C | Missense Mutation (SNP) | VAF 43/195 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.82); catalogued as COSV54991741; called by muse, mutect2, varscan2
- SF3B3 | c.1178A>G p.K393R | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV56789573; called by muse, mutect2, varscan2
- SPTB | c.2728G>A p.A910T | Missense Mutation (SNP) | VAF 103/250 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.017); catalogued as rs1566762795; called by muse, mutect2, varscan2
- TGM4 | c.908C>T p.T303M | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as rs373074233; called by muse, mutect2, varscan2
- TIE1 | c.2665G>C p.E889Q | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV65251326; called by muse, mutect2, varscan2
- TLR7 | c.440C>G p.P147R | Missense Mutation (SNP) | VAF 29/38 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101028075, COSV66124604; called by muse, mutect2, varscan2
- TMEM254 | c.207G>A p.W69* | Nonsense Mutation (SNP) | VAF 30/151 reads (20%) | catalogued as rs771419110; called by muse, mutect2, varscan2
- TNFRSF11B | c.439G>C p.D147H | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.438); catalogued as COSV52073378; called by muse, mutect2, varscan2
- TRGV3 | c.168C>A p.H56Q | Missense Mutation (SNP) | VAF 174/258 reads (67%) | SIFT tolerated (0.25); PolyPhen benign (0.163); catalogued as rs771339744; called by muse, mutect2, varscan2
- TRIM48 | c.459G>T p.W153C | Missense Mutation (SNP) | VAF 35/139 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as rs749231619, COSV101338354; called by muse, mutect2, varscan2
- TSHZ2 | c.382G>T p.V128F | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV100295715; called by muse, mutect2, varscan2
- TTN | c.17017A>G p.T5673A (on ENST00000591111; = p.T4746A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/25 reads (44%) | PolyPhen possibly damaging (0.554); catalogued as rs570762307; called by muse, mutect2, varscan2
- ZC3HAV1 | c.916G>T p.A306S | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT tolerated (0.81); PolyPhen benign (0.007); catalogued as rs780478917; called by muse, mutect2, varscan2
- ZMAT1 | c.379A>G p.N127D | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as rs749825296; called by muse, mutect2, varscan2
- ZNF124 | c.464G>T p.C155F (on ENST00000543802 / NM_001297568.1; = p.C93F on NM_003431.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1558385995; called by muse, mutect2, varscan2
- ZNF677 | c.124A>G p.R42G | Missense Mutation (SNP) | VAF 48/197 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as COSV61720248; called by muse, mutect2, varscan2
- ZZEF1 | c.2945C>T p.T982M | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.53); catalogued as rs774767038; called by muse, mutect2, varscan2
- ADGB | c.1699A>T p.T567S | Missense Mutation (SNP) | VAF 85/113 reads (75%) | SIFT tolerated (0.96); PolyPhen benign (0); called by muse, mutect2, varscan2
- AKAP12 | c.458A>G p.E153G | Missense Mutation (SNP) | VAF 87/110 reads (79%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- AMBRA1 | c.2617C>A p.P873T (on ENST00000458649 / NM_001367468.1; = p.P783T on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- AMER3 | c.1988G>T p.G663V | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- ANKRD26 | c.5000C>T p.A1667V | Missense Mutation (SNP) | VAF 23/34 reads (68%) | SIFT tolerated (0.15); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- ANKRD30B | c.1056G>T p.W352C | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ANKS1B | c.3008G>A p.R1003K | Missense Mutation (SNP) | VAF 120/209 reads (57%) | SIFT tolerated (0.14); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- ARHGAP22 | c.338G>C p.R113P | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.743); called by muse, mutect2
- ARHGAP42 | c.2039G>T p.W680L | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.63); PolyPhen benign (0.142); called by mutect2, varscan2
- ARID1A | c.4327A>T p.T1443S | Missense Mutation (SNP) | VAF 40/65 reads (62%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ASAH2 | c.302G>T p.G101V | Missense Mutation (SNP) | VAF 64/134 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- ATP13A4 | c.2880C>A p.F960L | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- BEND2 | c.1239C>A p.N413K | Missense Mutation (SNP) | VAF 37/54 reads (69%) | SIFT tolerated (0.06); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- BPTF | c.1628G>A p.G543D | Missense Mutation (SNP) | VAF 43/63 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BVES | c.923A>T p.Q308L | Missense Mutation (SNP) | VAF 60/107 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- C4orf54 | c.4034C>T p.S1345F | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- C6 | c.111_112del p.K37Nfs*17 | Frame Shift Del (DEL) | VAF 38/207 reads (18%) | called by mutect2, pindel, varscan2
- CALD1 | c.1922G>C p.G641A (on ENST00000361675 / NM_033138.4; = p.G386A on NM_004342.7) | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CBLN2 | c.454G>A p.V152M | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, varscan2
- CD2 | c.62-2A>T p.X21_splice | Splice Site (SNP) | VAF 6/15 reads (40%) | called by muse, mutect2, varscan2
- CDCA7L | c.1223G>T p.G408V | Missense Mutation (SNP) | VAF 51/67 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CDH18 | c.1390+1G>T p.X464_splice | Splice Site (SNP) | VAF 6/47 reads (13%) | called by muse, mutect2
- CDKL5 | c.1157C>A p.A386E | Missense Mutation (SNP) | VAF 8/186 reads (4%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.084); called by muse, mutect2
- CELF4 | c.885G>C p.Q295H | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CEP128 | c.1172A>C p.K391T | Missense Mutation (SNP) | VAF 63/128 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- CLGN | c.370G>C p.A124P | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- CLNK | c.904A>T p.K302* | Nonsense Mutation (SNP) | VAF 43/112 reads (38%) | called by muse, mutect2, varscan2
- CNBD1 | c.268C>A p.Q90K | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNTNAP5 | c.2936G>T p.G979V | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- COL6A6 | c.574C>A p.L192I | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- CPXCR1 | c.301G>T p.V101F | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- CSTL1 | c.286A>G p.T96A | Missense Mutation (SNP) | VAF 65/287 reads (23%) | SIFT tolerated (0.77); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CTNND2 | c.1203C>A p.S401R | Missense Mutation (SNP) | VAF 89/824 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- CTTN | c.599G>A p.G200D | Missense Mutation (SNP) | VAF 33/317 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DARS2 | c.671_681del p.K224Sfs*20 | Frame Shift Del (DEL) | VAF 32/136 reads (24%) | called by mutect2, pindel, varscan2
- DNAH3 | c.7658T>C p.I2553T | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- DRD3 | c.273G>T p.V91= | Splice Region (SNP) | VAF 16/74 reads (22%) | called by muse, mutect2, varscan2
- ELFN2 | c.1367C>G p.A456G | Missense Mutation (SNP) | VAF 80/148 reads (54%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EPB41L3 | c.1688G>A p.R563K | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- EPHB4 | c.929G>T p.R310L | Missense Mutation (SNP) | VAF 61/106 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- FAM111A | c.428C>A p.P143H | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FCMR | c.736G>C p.G246R | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- FSCB | c.401C>A p.T134N | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- FSCN1 | c.476C>A p.P159Q | Missense Mutation (SNP) | VAF 48/239 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GJA8 | c.1157C>A p.P386Q | Missense Mutation (SNP) | VAF 125/223 reads (56%) | SIFT tolerated (0.1); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- GP1BA | c.1166C>G p.S389* | Nonsense Mutation (SNP) | VAF 91/165 reads (55%) | called by muse, mutect2, varscan2
- GPATCH1 | c.2212G>T p.V738L | Missense Mutation (SNP) | VAF 97/152 reads (64%) | SIFT tolerated (0.28); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- GRIK4 | c.2740C>T p.R914C | Missense Mutation (SNP) | VAF 62/116 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- GYPA | c.336C>A p.Y112* | Nonsense Mutation (SNP) | VAF 27/97 reads (28%) | called by muse, mutect2, varscan2
- HYKK | c.166A>G p.K56E | Missense Mutation (SNP) | VAF 36/229 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KANSL3 | c.2059G>T p.G687W (on ENST00000666923 / NM_001349262.2; = p.G661W on NM_001115016.3) | Missense Mutation (SNP) | VAF 64/205 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- KCNQ3 | c.2027G>T p.R676M | Missense Mutation (SNP) | VAF 50/257 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- KLHL32 | c.8C>A p.S3Y | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- KRT19 | c.322C>G p.L108V | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- LAMA3 | c.4325C>T p.S1442L | Missense Mutation (SNP) | VAF 55/146 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- LARP1B | c.458G>C p.R153T | Missense Mutation (SNP) | VAF 59/103 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- LRG1 | c.386C>A p.T129N | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- LRP1B | c.11132-1G>T p.X3711_splice | Splice Site (SNP) | VAF 17/64 reads (27%) | called by muse, mutect2
- LRRC31 | c.1576C>T p.P526S | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.95); PolyPhen benign (0.003); called by muse, mutect2
- MAP3K4 | c.328C>G p.R110G | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MGAT4C | c.1070C>A p.A357E | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- MIA | c.354A>T p.K118N | Missense Mutation (SNP) | VAF 48/131 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- MKI67 | c.981G>T p.Q327H | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- MLH1 | c.1345G>T p.G449W | Missense Mutation (SNP) | VAF 36/61 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- MMP11 | c.807_817del p.A270Pfs*8 | Frame Shift Del (DEL) | VAF 78/176 reads (44%) | called by mutect2, pindel, varscan2
- MRC1 | c.1069G>T p.D357Y | Missense Mutation (SNP) | VAF 44/80 reads (55%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- MRC1 | c.3493C>T p.Q1165* | Nonsense Mutation (SNP) | VAF 102/183 reads (56%) | called by muse, mutect2, varscan2
- MTRR | c.1850G>T p.R617I (on ENST00000264668; = p.R590I on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/410 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MYZAP | c.1202A>C p.E401A | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NCCRP1 | c.812T>C p.V271A | Missense Mutation (SNP) | VAF 35/331 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- NLRP9 | c.207G>A p.W69* | Nonsense Mutation (SNP) | VAF 162/300 reads (54%) | called by muse, mutect2, varscan2
- NREP | c.81+5G>C | Splice Region (SNP) | VAF 11/36 reads (31%) | called by muse, mutect2, varscan2
- NUMA1 | c.4732C>G p.Q1578E | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- OR2G2 | c.382G>T p.A128S | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- OR5J2 | c.664G>T p.A222S | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.505); called by muse, mutect2
- OR5L1 | c.325G>T p.V109F | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- OR5L2 | c.404C>A p.T135N | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- OR8H3 | c.107A>G p.Y36C | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OTOL1 | c.1337C>T p.S446L | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PALB2 | c.1462del p.S488Afs*73 | Frame Shift Del (DEL) | VAF 7/36 reads (19%) | called by mutect2, pindel, varscan2
- PCDH15 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 39/156 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- PCDHB5 | c.79G>C p.G27R | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PCDHB5 | c.80G>T p.G27V | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- PGAP3 | c.529C>G p.L177V | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- PLCB4 | c.2449A>G p.N817D | Missense Mutation (SNP) | VAF 47/145 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- PLCD3 | c.1996G>C p.V666L | Missense Mutation (SNP) | VAF 31/52 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- PLPP6 | c.301A>T p.I101F | Missense Mutation (SNP) | VAF 8/204 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2
- PNPLA5 | c.44C>G p.S15C | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- POLR3A | c.3825G>T p.M1275I | Missense Mutation (SNP) | VAF 36/434 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- POU6F1 | c.1620G>T p.E540D | Missense Mutation (SNP) | VAF 111/367 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- PSG4 | c.935_948del p.I312Rfs*6 | Frame Shift Del (DEL) | VAF 39/132 reads (30%) | called by mutect2, pindel, varscan2
- PTP4A1 | c.237G>C p.Q79H | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- RBMXL3 | c.706G>T p.G236C | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- RHAG | c.1129C>A p.L377M | Missense Mutation (SNP) | VAF 87/199 reads (44%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- RNF112 | c.1247G>T p.R416M | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- RP1 | c.677C>A p.P226Q | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RTEL1 | c.406T>C p.C136R | Missense Mutation (SNP) | VAF 48/306 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- RYR3 | c.12061C>A p.L4021I (on ENST00000389232; = p.L4022I on NM_001036.6) | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- SALL3 | c.2002G>T p.V668L | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SAXO2 | c.110A>G p.Y37C | Missense Mutation (SNP) | VAF 52/108 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- SERPINA1 | c.550T>A p.Y184N | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- SGCB | c.19G>T p.A7S | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC14A1 | c.338A>T p.D113V | Missense Mutation (SNP) | VAF 72/194 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SLC41A3 | c.108A>T p.E36D | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- SLC8A3 | c.163A>T p.K55* | Nonsense Mutation (SNP) | VAF 14/99 reads (14%) | called by muse, mutect2, varscan2
- SNX2 | c.715C>G p.L239V | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- SPARC | c.120+1G>A p.X40_splice | Splice Site (SNP) | VAF 44/81 reads (54%) | called by muse, mutect2, varscan2
- SPTB | c.3344A>C p.D1115A | Missense Mutation (SNP) | VAF 93/446 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SREK1IP1 | c.148G>C p.E50Q | Missense Mutation (SNP) | VAF 52/99 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- SYNGAP1 | c.3872T>A p.L1291Q | Missense Mutation (SNP) | VAF 283/410 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- SYNRG | c.386A>T p.Q129L | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.288); called by muse, mutect2
- TCP11X2 | c.943G>T p.D315Y | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by mutect2, varscan2
- TERT | c.1116G>T p.M372I | Missense Mutation (SNP) | VAF 336/448 reads (75%) | SIFT tolerated (0.25); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- THSD7A | c.2880dup p.Y961Ifs*2 | Frame Shift Ins (INS) | VAF 14/169 reads (8%) | called by pindel, varscan2*
- TMTC4 | c.1019C>T p.S340L (on ENST00000376234 / NM_001350577.2; = p.S359L on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 89/167 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TNN | c.1343dup p.N448Kfs*5 | Frame Shift Ins (INS) | VAF 8/35 reads (23%) | called by mutect2, pindel
- TNNC2 | c.295T>C p.C99R | Missense Mutation (SNP) | VAF 59/110 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TRBV27 | c.216G>C p.E72D | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.79); PolyPhen benign (0.001); called by muse, varscan2
- TRIB2 | c.292C>T p.Q98* | Nonsense Mutation (SNP) | VAF 32/74 reads (43%) | called by mutect2, varscan2
- TRIM64B | c.1196T>G p.V399G | Missense Mutation (SNP) | VAF 80/297 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TVP23A | c.601C>G p.Q201E | Missense Mutation (SNP) | VAF 59/106 reads (56%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- UGT3A1 | c.750C>G p.N250K | Missense Mutation (SNP) | VAF 12/338 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2
- VNN2 | c.957T>A p.N319K | Missense Mutation (SNP) | VAF 187/236 reads (79%) | SIFT tolerated (0.07); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- VPS8 | c.1344T>A p.N448K (on ENST00000625842 / NM_001349294.1; = p.N446K on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- WDR13 | c.607G>C p.V203L | Missense Mutation (SNP) | VAF 55/80 reads (69%) | SIFT tolerated (0.42); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- YTHDF3 | c.10A>G p.T4A | Missense Mutation (SNP) | VAF 90/296 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0.096); called by muse, varscan2
- ZNF638 | c.5053G>A p.E1685K | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF729 | c.2697G>T p.K899N | Missense Mutation (SNP) | VAF 39/69 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF888 | c.143-1G>C p.X48_splice | Splice Site (SNP) | VAF 41/92 reads (45%) | called by muse, mutect2, varscan2
- ZSCAN5C | c.528A>T p.E176D | Missense Mutation (SNP) | VAF 27/206 reads (13%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- ZSWIM5 | c.987C>A p.D329E | Missense Mutation (SNP) | VAF 15/172 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0.107); called by muse, mutect2
- ACTL9 | c.582G>T p.L194= | Silent (SNP) | VAF 63/115 reads (55%) | called by muse, mutect2, varscan2
- ADGRG7 | c.1941G>A p.S647= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs375617780; called by muse, mutect2, varscan2
- ALPK2 | c.3510G>A p.V1170= | Silent (SNP) | VAF 17/82 reads (21%) | called by muse, mutect2, varscan2
- ANKRD13B | c.708G>T p.A236= | Silent (SNP) | VAF 17/121 reads (14%) | catalogued as rs773640250, COSV67473397; called by muse, mutect2, varscan2
- ARHGAP20 | c.1170A>G p.K390= | Silent (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
- BRINP3 | c.1275G>T p.S425= | Silent (SNP) | VAF 78/201 reads (39%) | catalogued as COSV66524663; called by muse, mutect2, varscan2
- C15orf65 | c.81T>A p.P27= | Silent (SNP) | VAF 9/34 reads (26%) | called by muse, mutect2
- CALCOCO1 | c.963G>C p.V321= | Silent (SNP) | VAF 12/256 reads (5%) | called by muse, mutect2
- CAND1 | c.3384G>A p.V1128= | Silent (SNP) | VAF 25/80 reads (31%) | called by muse, mutect2, varscan2
- CCDC24 | c.240C>G p.L80= | Silent (SNP) | VAF 48/228 reads (21%) | catalogued as rs1409865773; called by muse, mutect2, varscan2
- CENPE | c.4965C>T p.T1655= | Silent (SNP) | VAF 65/187 reads (35%) | called by muse, mutect2, varscan2
- CFAP54 | c.4446T>A p.A1482= | Silent (SNP) | VAF 34/183 reads (19%) | called by muse, mutect2, varscan2
- CHD6 | c.4173C>T p.S1391= | Silent (SNP) | VAF 99/219 reads (45%) | called by muse, mutect2, varscan2
- CILK1 | c.1689C>G p.V563= (on ENST00000350082 / NM_001375397.1; = p.V556= on NM_014920.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 11/87 reads (13%) | called by muse, mutect2, varscan2
- CNOT2 | c.321G>A p.P107= | Silent (SNP) | VAF 22/186 reads (12%) | catalogued as rs181208252; called by muse, mutect2, varscan2
- DNAH17 | c.3084A>G p.T1028= | Silent (SNP) | VAF 11/30 reads (37%) | called by muse, mutect2, varscan2
- DNMT1 | c.2400G>T p.G800= | Silent (SNP) | VAF 80/142 reads (56%) | called by muse, mutect2, varscan2
- DOK1 | c.381G>T p.A127= | Silent (SNP) | VAF 138/315 reads (44%) | catalogued as rs145784646; called by muse, mutect2, varscan2
- EPPK1 | c.5460G>A p.Q1820= | Silent (SNP) | VAF 28/100 reads (28%) | called by muse, mutect2, varscan2
- EXOC6B | c.1935C>G p.L645= | Silent (SNP) | VAF 25/215 reads (12%) | called by muse, mutect2, varscan2
- FAT3 | c.10041T>C p.S3347= | Silent (SNP) | VAF 42/65 reads (65%) | called by muse, mutect2, varscan2
- GABRE | c.1470G>A p.V490= | Silent (SNP) | VAF 38/52 reads (73%) | called by muse, mutect2, varscan2
- GABRG1 | c.864T>C p.S288= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as rs1408411240; called by muse, mutect2, varscan2
- GCNT3 | c.1162C>A p.R388= | Silent (SNP) | VAF 10/52 reads (19%) | called by muse, mutect2, varscan2
- GNAS | c.591G>T p.L197= | Silent (SNP) | VAF 254/499 reads (51%) | called by muse, mutect2, varscan2
- GSKIP | c.403A>C p.R135= | Silent (SNP) | VAF 33/70 reads (47%) | called by muse, mutect2, varscan2
- HCN1 | c.1399C>A p.R467= | Silent (SNP) | VAF 28/302 reads (9%) | catalogued as COSV57529468; called by muse, mutect2
- IL16 | c.3765A>G p.L1255= (on ENST00000302987 / NM_172217.5; = p.L554= on NM_004513.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/394 reads (8%) | called by muse, mutect2
- IL6R | c.156G>A p.P52= | Silent (SNP) | VAF 31/316 reads (10%) | called by muse, mutect2, varscan2
- KRT73 | c.54C>T p.S18= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as rs74778340; called by muse, mutect2, varscan2
- KRT74 | c.1293G>C p.L431= | Silent (SNP) | VAF 164/462 reads (35%) | catalogued as COSV59770881; called by muse, mutect2, varscan2
- MAB21L1 | c.333C>A p.S111= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV59798730; called by muse, mutect2, varscan2
- MAEL | c.774C>T p.L258= | Silent (SNP) | VAF 14/72 reads (19%) | called by muse, mutect2, varscan2
- MCM3AP | c.3348T>A p.A1116= | Silent (SNP) | VAF 71/124 reads (57%) | called by muse, mutect2, varscan2
- MRC1 | c.576C>T p.L192= | Silent (SNP) | VAF 116/216 reads (54%) | catalogued as rs1156971855; called by muse, varscan2
- MUC6 | c.6171C>A p.S2057= | Silent (SNP) | VAF 24/228 reads (11%) | called by muse, varscan2
- MXRA5 | c.6444C>T p.I2148= | Silent (SNP) | VAF 43/63 reads (68%) | catalogued as COSV54238750; called by muse, mutect2, varscan2
- NR4A3 | c.1647A>G p.L549= | Silent (SNP) | VAF 23/33 reads (70%) | called by muse, varscan2
- NUTM1 | c.1803A>T p.L601= | Silent (SNP) | VAF 18/57 reads (32%) | called by muse, mutect2, varscan2
- OPN3 | c.174C>T p.N58= | Silent (SNP) | VAF 41/111 reads (37%) | called by muse, mutect2, varscan2
- OR13G1 | c.249A>G p.L83= | Silent (SNP) | VAF 43/154 reads (28%) | catalogued as rs746801442, COSV62943591; called by muse, mutect2, varscan2
- OR2D2 | c.816G>T p.V272= | Silent (SNP) | VAF 28/84 reads (33%) | called by muse, mutect2, varscan2
- OR5L2 | c.405C>A p.T135= | Silent (SNP) | VAF 16/45 reads (36%) | called by muse, mutect2, varscan2
- OR8H2 | c.705G>A p.Q235= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV57944435, COSV57946162; called by muse, mutect2, varscan2
- OSMR | c.285G>T p.L95= | Silent (SNP) | VAF 51/377 reads (14%) | catalogued as rs1337663817; called by muse, mutect2, varscan2
- PHACTR3 | c.1581A>C p.A527= | Silent (SNP) | VAF 6/41 reads (15%) | called by muse, mutect2, varscan2
- PLB1 | c.405C>T p.H135= | Silent (SNP) | VAF 36/115 reads (31%) | catalogued as rs767065976, COSV59836279; called by muse, mutect2, varscan2
- PLXNC1 | c.1386G>C p.S462= | Silent (SNP) | VAF 10/196 reads (5%) | catalogued as COSV99312308; called by muse, mutect2
- PRKACG | c.912C>T p.I304= | Silent (SNP) | VAF 38/126 reads (30%) | catalogued as COSV55242115; called by muse, mutect2, varscan2
- PRRT4 | c.951A>G p.P317= | Silent (SNP) | VAF 27/144 reads (19%) | called by muse, mutect2, varscan2
- PTPRF | c.3282C>T p.R1094= | Silent (SNP) | VAF 32/330 reads (10%) | catalogued as rs1165039229; called by muse, mutect2
- RAPGEF2 | c.813C>T p.V271= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV52431020; called by muse, mutect2, varscan2
- RNF180 | c.459G>C p.L153= | Silent (SNP) | VAF 40/59 reads (68%) | called by muse, mutect2, varscan2
- RSPH6A | c.816G>A p.A272= | Silent (SNP) | VAF 75/219 reads (34%) | catalogued as rs767244839, COSV55575410; called by muse, mutect2, varscan2
- SEC23B | c.2281C>T p.L761= | Silent (SNP) | VAF 10/257 reads (4%) | called by muse, mutect2
- SIGLEC6 | c.321C>T p.S107= | Silent (SNP) | VAF 68/124 reads (55%) | called by muse, mutect2, varscan2
- SLC34A3 | c.339G>C p.V113= | Silent (SNP) | VAF 89/171 reads (52%) | called by muse, mutect2, varscan2
- SLC9C2 | c.2898T>C p.T966= | Silent (SNP) | VAF 22/43 reads (51%) | called by muse, mutect2, varscan2
- SPTAN1 | c.4449G>C p.L1483= | Silent (SNP) | VAF 50/75 reads (67%) | called by muse, mutect2, varscan2
- ST3GAL1 | c.216C>T p.A72= | Silent (SNP) | VAF 29/98 reads (30%) | called by muse, mutect2, varscan2
- SYNE2 | c.16935G>A p.Q5645= | Silent (SNP) | VAF 21/127 reads (17%) | catalogued as COSV59938348; called by muse, mutect2, varscan2
- TMEM176B | c.393C>G p.L131= | Silent (SNP) | VAF 84/124 reads (68%) | catalogued as COSV58440414; called by muse, mutect2
- TTN | c.48388T>C p.L16130= (on ENST00000591111; = p.L8706= on NM_003319.4) | Silent (SNP) | VAF 10/53 reads (19%) | called by muse, mutect2, varscan2
- UHRF2 | c.333A>G p.P111= | Silent (SNP) | VAF 38/66 reads (58%) | called by muse, mutect2, varscan2
- UNC5B | c.1143G>T p.V381= | Silent (SNP) | VAF 37/76 reads (49%) | called by muse, mutect2, varscan2
- USP2 | c.651C>T p.P217= | Silent (SNP) | VAF 3/17 reads (18%) | called by muse, varscan2
- WDR72 | c.2199C>A p.A733= | Silent (SNP) | VAF 10/40 reads (25%) | called by muse, mutect2
- Z83844.2 | c.1335C>T p.T445= | Silent (SNP) | VAF 20/152 reads (13%) | catalogued as rs767491821; called by muse, mutect2, varscan2
- ZNF407 | c.3204G>A p.E1068= | Silent (SNP) | VAF 13/33 reads (39%) | called by muse, mutect2, varscan2
- ZNF496 | c.162G>C p.A54= | Silent (SNP) | VAF 19/182 reads (10%) | catalogued as COSV54178030; called by muse, mutect2, varscan2
- ZNF85 | c.1734C>A p.S578= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV60215765; called by muse, mutect2, varscan2
- AC044798.1 | n.172G>C | RNA (SNP) | VAF 11/47 reads (23%) | called by muse, mutect2, varscan2
- ACBD6 | c.*1663G>A | 3'UTR (SNP) | VAF 11/56 reads (20%) | catalogued as rs760996220; called by muse, mutect2, varscan2
- AOAH | c.128-3382C>T | Intron (SNP) | VAF 38/62 reads (61%) | called by muse, varscan2
- C1QA | c.*15C>A | 3'UTR (SNP) | VAF 55/99 reads (56%) | called by muse, mutect2, varscan2
- C1QL3 | c.-5del | 5'UTR (DEL) | VAF 60/134 reads (45%) | called by mutect2, pindel, varscan2
- CHMP1A | c.106-9G>T | Intron (SNP) | VAF 37/159 reads (23%) | called by muse, mutect2, varscan2
- CLCN5 | c.17-28989T>G | Intron (SNP) | VAF 8/14 reads (57%) | called by muse, mutect2, varscan2
- CNKSR1 | c.*145C>G | 3'UTR (SNP) | VAF 20/120 reads (17%) | called by muse, mutect2, varscan2
- CSH1 | c.457-49G>T | Intron (SNP) | VAF 119/199 reads (60%) | called by muse, mutect2, varscan2
- CSH1 | c.457-50G>T | Intron (SNP) | VAF 121/202 reads (60%) | called by muse, mutect2, varscan2
- DHX37 | c.2983+43G>A | Intron (SNP) | VAF 13/46 reads (28%) | catalogued as rs756498981, COSV58133262; called by muse, mutect2, varscan2
- DIS3L2 | c.2497-108del | Intron (DEL) | VAF 27/48 reads (56%) | called by mutect2, pindel, varscan2
- ERI2 | c.23+18G>T | Intron (SNP) | VAF 47/70 reads (67%) | called by muse, mutect2, varscan2
- ETS1 | chr11:128527037 G>T | 5'Flank (SNP) | VAF 11/20 reads (55%) | called by muse, mutect2, varscan2
- GGTLC2 | chr22:22642919 del C | 5'Flank (DEL) | VAF 106/349 reads (30%) | called by mutect2, pindel, varscan2
- GORAB | c.419+24C>G | Intron (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2, varscan2
- GVINP1 | n.3638A>G | RNA (SNP) | VAF 38/70 reads (54%) | called by muse, mutect2, varscan2
- HBE1 | c.-267+102851A>T | Intron (SNP) | VAF 50/92 reads (54%) | catalogued as COSV59673160; called by muse, mutect2, varscan2
- HERC2P3 | n.1621G>C | RNA (SNP) | VAF 28/234 reads (12%) | called by muse, mutect2, varscan2
- HTR1A | c.-8G>A | 5'UTR (SNP) | VAF 20/207 reads (10%) | catalogued as rs1561279508; called by muse, mutect2
- IGKV3D-15 | c.-12C>A | 5'UTR (SNP) | VAF 64/309 reads (21%) | called by muse, mutect2, varscan2
- KIF16B | c.3498+2876C>G | Intron (SNP) | VAF 42/161 reads (26%) | called by muse, mutect2, varscan2
- LGALS12 | c.-1C>G | 5'UTR (SNP) | VAF 39/235 reads (17%) | called by muse, mutect2, varscan2
- LINC02817 | n.384G>T | RNA (SNP) | VAF 38/127 reads (30%) | called by muse, mutect2, varscan2
- MBD5 | c.2845+555C>T | Intron (SNP) | VAF 44/87 reads (51%) | catalogued as rs990231341; called by muse, mutect2, varscan2
- MKS1 | c.1490+13G>T | Intron (SNP) | VAF 137/351 reads (39%) | called by muse, mutect2, varscan2
- MKS1 | c.1490+12G>T | Intron (SNP) | VAF 134/348 reads (39%) | called by muse, mutect2, varscan2
- MYB | c.-21G>A | 5'UTR (SNP) | VAF 27/32 reads (84%) | called by mutect2, varscan2
- NINJ2 | c.34-44175T>A | Intron (SNP) | VAF 34/203 reads (17%) | called by muse, mutect2, varscan2
- NOC2LP2 | n.418A>T | RNA (SNP) | VAF 85/137 reads (62%) | catalogued as rs750170224; called by muse, mutect2, varscan2
- NXF1 | c.-8G>C | 5'UTR (SNP) | VAF 58/114 reads (51%) | called by muse, mutect2, varscan2
- NXF5 | n.1392C>T | RNA (SNP) | VAF 75/95 reads (79%) | called by muse, mutect2, varscan2
- PCP4 | c.62-2931G>A | Intron (SNP) | VAF 24/63 reads (38%) | called by muse, mutect2, varscan2
- PRPF40A | c.770-21A>G | Intron (SNP) | VAF 13/38 reads (34%) | called by muse, mutect2, varscan2
- PTPRR | c.628-311G>C | Intron (SNP) | VAF 19/67 reads (28%) | called by muse, mutect2, varscan2
- SH3YL1 | c.291+3991C>T | Intron (SNP) | VAF 36/125 reads (29%) | called by muse, mutect2, varscan2
- TAAR3P | n.955T>A | RNA (SNP) | VAF 87/112 reads (78%) | called by muse, mutect2, varscan2
- TSHR | c.*12A>G | 3'UTR (SNP) | VAF 19/103 reads (18%) | catalogued as rs758247685; called by muse, mutect2, varscan2
- UBE3A | c.29+42_29+46del | Intron (DEL) | VAF 22/89 reads (25%) | called by mutect2, pindel, varscan2
- UGT2B4 | c.-1G>T | 5'UTR (SNP) | VAF 7/15 reads (47%) | catalogued as rs764831293; called by muse, varscan2
- UGT2B4 | c.-2G>T | 5'UTR (SNP) | VAF 7/14 reads (50%) | called by muse, mutect2, varscan2
- WASH8P | n.1026G>T | RNA (SNP) | VAF 48/727 reads (7%) | catalogued as rs1555061129; called by muse, mutect2
- ZEB2 | c.73+4729G>A | Intron (SNP) | VAF 4/28 reads (14%) | catalogued as rs1399046590; called by muse, mutect2, varscan2
- ZNF233 | c.-95_-94insA | 5'UTR (INS) | VAF 15/57 reads (26%) | called by mutect2, pindel*, varscan2
